HCMI case HCM-WCMC-0747-C50 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/74016d27-4ade-46de-85d9-504e6e840042

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Year of birth: 1976; Vital status: Alive.

Diagnoses (2)
1. Lobular carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8520/3; ICD-10 code: C50.1; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 43.2 years (15,793 days); AJCC staging edition: 8th; AJCC clinical stage: Stage IIA; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Prior treatment: No.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 43 days.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Tamoxifen; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 106 days; Days to treatment end: 411 days (1.1 years).
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Leuprolide; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 435 days (1.2 years); Days to treatment end: 435 days (1.2 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 510 days (1.4 years); Days to treatment end: 552 days (1.5 years).
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 580 days (1.6 years); Days to treatment end: 613 days (1.7 years).
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Letrozole + Leuprolide; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 594 days (1.6 years); Days to treatment end: 764 days (2.1 years).
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Anastrozole + Leuprolide; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 745 days (2.0 years); Days to treatment end: 1,175 days (3.2 years); Treatment outcome: Treatment Ongoing.
   Recorded as not given: neoadjuvant treatment (type not reported); prevention Hormone Therapy; adjuvant Immunotherapy (Including Vaccines), for residual disease; adjuvant Targeted Molecular Therapy, for residual disease.
2. Lobular carcinoma, NOS: ICD-O-3 morphology code: 8520/3; ICD-10 code: C50.111; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Laterality: Right; Classification of tumor: recurrence; Age at diagnosis: 44.3 years (16,192 days); Days to diagnosis: 399 days (1.1 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Leuprolide Acetate + Tamoxifen; Treatment intent type: Maintenance Therapy; Days to treatment start: 106 days; Days to treatment end: 928 days (2.5 years); Treatment outcome: Treatment Ongoing.
   Treatment given: Treatment type: Hormone Therapy; Treatment intent type: Prevention.

Follow-up (2 entries)
- Days to follow up: 1,180 days (3.2 years); Disease response: Stable Disease; Progression or recurrence: No.
- Follow-up contacts recording only the day: day 0, day 614.

Molecular and laboratory tests
- ERBB2 (IHC): Negative.
- PGR (IHC): Positive.

Other clinical attributes
- Day 0: Menopause status: Premenopausal.
- Timepoint category: Initial Diagnosis; Weight: 70.8 kg; Height: 165.1 cm; BMI: 26.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Cancer.

Biospecimens (5 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-WCMC-0747-C50-01A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide HCM-WCMC-0747-C50-01A-S2-HE: Section location: Bottom; Percent tumor cells: 50; Percent tumor nuclei: 80; Percent normal cells: 26; Percent necrosis: 0; Percent stromal cells: 24; Percent lymphocyte infiltration: 14; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 0.
  Slide HCM-WCMC-0747-C50-01A-S1-HE: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 85; Percent normal cells: 3; Percent necrosis: 0; Percent stromal cells: 12; Percent lymphocyte infiltration: 4; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 3.
- Sample HCM-WCMC-0747-C50-05A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample HCM-WCMC-0747-C50-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Buffy Coat; Preservation method: Frozen.
- Sample HCM-WCMC-0747-C50-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Cryopreserved; Passage count: 10.
- Sample HCM-WCMC-0747-C50-85P: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
